Somatic mutation profile of tumor specimen C3N-02682-02 (aliquot CPT0224900006) from CPTAC case C3N-02682, project CPTAC-3 (Brain — Gliomas). Sex at birth: male; Vital status: Dead; Primary diagnosis: Glioblastoma; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 58.4 years (21,329 days).
Specimen C3N-02682-02: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Brain; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) bf416b91-a953-46c2-baec-5b86df39b1ec.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3N-02682-31 (Blood Derived Normal), aliquot CPT0224920002; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/25886489-f702-4752-8bcb-9c52770da3e0

The open-access MAF lists 56 somatic variants for this specimen: 37 protein-altering or splice-affecting, 14 silent, 5 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 30, Silent 14, Nonsense Mutation 5, 3'UTR 3, Frame Shift Del 2, Intron 1, 5'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- NEXMIF | c.1441C>T p.R481* | Nonsense Mutation (SNP) | VAF 38/60 reads (63%) | catalogued as rs886041701, COSV50111243; ClinVar: pathogenic; called by muse, mutect2, varscan2
- ATP6V0A4 | c.1249G>A p.V417M | Missense Mutation (SNP) | VAF 159/613 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.937); catalogued as rs530406140; called by muse, mutect2, varscan2
- BARX2 | c.409C>T p.R137C | Missense Mutation (SNP) | VAF 58/164 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV55651171; called by muse, mutect2, varscan2
- BRPF3 | c.2042G>A p.R681H | Missense Mutation (SNP) | VAF 204/546 reads (37%) | SIFT deleterious (0.03); PolyPhen benign (0.041); catalogued as rs1171928243, COSV60206374; called by muse, mutect2, varscan2
- CCR5 | c.402_403del p.F135Cfs*92 | Frame Shift Del (DEL) | VAF 48/202 reads (24%) | catalogued as rs1215591945; called by pindel, varscan2
- CD53 | c.371G>A p.R124H | Missense Mutation (SNP) | VAF 89/317 reads (28%) | SIFT tolerated (0.32); PolyPhen benign (0.007); catalogued as rs748379786; called by muse, mutect2, varscan2
- CFHR3 | c.368C>T p.A123V | Missense Mutation (SNP) | VAF 163/473 reads (34%) | SIFT tolerated (0.11); PolyPhen benign (0.028); catalogued as rs1440187744, COSV66401591; called by muse, mutect2, varscan2
- CFTR | c.2897C>T p.T966M | Missense Mutation (SNP) | VAF 52/325 reads (16%) | SIFT tolerated (0.1); PolyPhen benign (0.079); catalogued as rs1562911760; called by muse, mutect2, varscan2
- CLCN1 | c.2338C>T p.R780C | Missense Mutation (SNP) | VAF 163/598 reads (27%) | SIFT tolerated (0.05); PolyPhen benign (0.394); catalogued as rs138062220, COSV58375387; called by muse, mutect2, varscan2
- COL6A3 | c.4060G>A p.D1354N | Missense Mutation (SNP) | VAF 233/693 reads (34%) | SIFT tolerated (0.17); PolyPhen benign (0.203); catalogued as rs559206141, COSV55106892, COSV55109871; called by muse, mutect2, varscan2
- CSF2RA | c.596G>A p.R199Q | Missense Mutation (SNP) | VAF 162/427 reads (38%) | SIFT tolerated (0.76); PolyPhen benign (0.046); catalogued as rs144461826, COSV62623548; called by muse, mutect2, varscan2
- CYP4A22 | c.1429C>T p.R477C | Missense Mutation (SNP) | VAF 55/165 reads (33%) | SIFT deleterious (0.04); PolyPhen benign (0.219); catalogued as rs777531624; called by muse, mutect2, varscan2
- DZIP1 | c.2587G>A p.D863N (on ENST00000347108; = p.D844N on NM_014934.5) | Missense Mutation (SNP) | VAF 32/173 reads (18%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as rs966468878; called by muse, mutect2, varscan2
- FKBP6 | c.131G>A p.R44Q | Missense Mutation (SNP) | VAF 250/1193 reads (21%) | SIFT tolerated (0.4); PolyPhen benign (0.041); catalogued as rs782399413, COSV52720651; called by muse, mutect2, varscan2
- FSIP2 | c.706C>T p.R236* | Nonsense Mutation (SNP) | VAF 5/92 reads (5%) | catalogued as rs1246929424, COSV58098015; called by muse, mutect2
- GOLGA8S | c.382G>A p.E128K | Missense Mutation (SNP) | VAF 12/76 reads (16%) | SIFT tolerated (0.48); PolyPhen benign (0.012); catalogued as rs1427517365; called by mutect2, varscan2
- HMX1 | c.365G>A p.G122D | Missense Mutation (SNP) | VAF 104/277 reads (38%) | SIFT deleterious (0.05); PolyPhen benign (0.362); catalogued as rs1216106828; called by muse, mutect2, varscan2
- NARF | c.1049G>A p.R350Q | Missense Mutation (SNP) | VAF 84/171 reads (49%) | SIFT deleterious (0); PolyPhen possibly damaging (0.473); catalogued as rs1013591686, COSV59112797; called by muse, mutect2, varscan2
- OR52R1 | c.401G>A p.R134Q | Missense Mutation (SNP) | VAF 117/317 reads (37%) | SIFT deleterious (0.04); PolyPhen benign (0.011); catalogued as rs989215241; called by muse, mutect2, varscan2
- PABPC5 | c.518G>A p.R173H | Missense Mutation (SNP) | VAF 129/177 reads (73%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.842); catalogued as COSV100442599; called by muse, mutect2, varscan2
- PRKRIP1 | c.241G>A p.V81M | Missense Mutation (SNP) | VAF 145/607 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs782354296; called by muse, mutect2, varscan2
- PRX | c.2449C>T p.R817C | Missense Mutation (SNP) | VAF 364/1060 reads (34%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.809); catalogued as rs147441856; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- PTPN9 | c.1274G>A p.R425Q | Missense Mutation (SNP) | VAF 55/207 reads (27%) | SIFT tolerated (0.64); PolyPhen benign (0.001); catalogued as rs745713152, COSV60724560; called by muse, mutect2, varscan2
- TAFA1 | c.380C>T p.T127M | Missense Mutation (SNP) | VAF 50/127 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1369667825; called by muse, mutect2, varscan2
- TMCC2 | c.1691G>A p.R564Q | Missense Mutation (SNP) | VAF 108/267 reads (40%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.99); catalogued as rs1390128132; called by mutect2, varscan2
- TRPM3 | c.1657G>A p.G553S (on ENST00000357533 / NM_001366142.2; = p.G398S on NM_024971.6) | Missense Mutation (SNP) | VAF 42/141 reads (30%) | SIFT tolerated, low confidence (0.38); PolyPhen benign (0.015); catalogued as rs367841372, COSV62584743; called by muse, mutect2, varscan2
- ZNF492 | c.31G>A p.V11M | Missense Mutation (SNP) | VAF 91/345 reads (26%) | SIFT deleterious (0); PolyPhen benign (0.014); catalogued as rs569293451, COSV101513940, COSV71762348; called by muse, mutect2, varscan2
- ADAMTSL3 | c.2920G>T p.A974S | Missense Mutation (SNP) | VAF 119/417 reads (29%) | SIFT tolerated (0.17); PolyPhen probably damaging (0.936); called by muse, mutect2, varscan2
- ARHGAP19 | c.418G>A p.G140S | Missense Mutation (SNP) | VAF 87/149 reads (58%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- CCDC185 | c.1510A>T p.R504* | Nonsense Mutation (SNP) | VAF 139/393 reads (35%) | called by muse, mutect2, varscan2
- DEUP1 | c.314_317del p.N105Tfs*5 | Frame Shift Del (DEL) | VAF 32/87 reads (37%) | called by mutect2, pindel, varscan2
- KMT5B | c.832A>G p.N278D | Missense Mutation (SNP) | VAF 27/77 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- LMF2 | c.157C>T p.R53C | Missense Mutation (SNP) | VAF 254/659 reads (39%) | SIFT tolerated (0.18); PolyPhen benign (0.42); called by muse, mutect2, varscan2
- MGST1 | c.379C>T p.Q127* | Nonsense Mutation (SNP) | VAF 42/127 reads (33%) | called by muse, mutect2, varscan2
- MTUS2 | c.2410A>G p.T804A | Missense Mutation (SNP) | VAF 168/411 reads (41%) | SIFT tolerated (0.69); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- RECQL5 | c.2595C>G p.S865R | Missense Mutation (SNP) | VAF 146/699 reads (21%) | SIFT tolerated (0.13); PolyPhen benign (0); called by muse, mutect2, varscan2
- RELCH | c.712C>T p.R238* | Nonsense Mutation (SNP) | VAF 71/193 reads (37%) | called by muse, mutect2, varscan2
- BLK | c.1026G>A p.A342= | Silent (SNP) | VAF 243/703 reads (35%) | catalogued as rs756828789, COSV52055202; called by muse, mutect2, varscan2
- C1orf68 | c.393G>A p.T131= | Silent (SNP) | VAF 205/552 reads (37%) | catalogued as rs753395174; called by muse, mutect2, varscan2
- CGNL1 | c.3396G>T p.R1132= | Silent (SNP) | VAF 95/278 reads (34%) | called by muse, mutect2, varscan2
- GABRG1 | c.330A>G p.T110= | Silent (SNP) | VAF 10/76 reads (13%) | called by muse, varscan2
- NLRP4 | c.768G>A p.P256= | Silent (SNP) | VAF 124/315 reads (39%) | catalogued as rs140962628, COSV56713093, COSV56718330; called by muse, mutect2, varscan2
- PISD | c.681C>T p.D227= (on ENST00000439502 / NM_001326412.1; = p.D193= on NM_014338.3) | Silent (SNP) | VAF 110/339 reads (32%) | called by muse, mutect2, varscan2
- PLIN4 | c.1926C>T p.T642= (on ENST00000301286; = p.T657= on NM_001367868.2) | Silent (SNP) | VAF 344/1030 reads (33%) | catalogued as rs971521586; called by muse, varscan2
- RERE | c.2556C>T p.P852= | Silent (SNP) | VAF 32/74 reads (43%) | catalogued as rs772244383; called by mutect2, varscan2
- RPS6KA1 | c.1248C>T p.D416= | Silent (SNP) | VAF 119/363 reads (33%) | catalogued as rs149144046; called by muse, mutect2, varscan2
- SLIT2 | c.3147C>T p.H1049= | Silent (SNP) | VAF 115/379 reads (30%) | catalogued as rs756872945, COSV56582524, COSV56598699; called by muse, mutect2, varscan2
- SULT1E1 | c.756G>A p.S252= | Silent (SNP) | VAF 65/236 reads (28%) | catalogued as rs376968582; called by muse, mutect2, varscan2
- TCL1B | c.126G>A p.S42= | Silent (SNP) | VAF 82/214 reads (38%) | catalogued as rs563494390, COSV61551921; called by muse, mutect2, varscan2
- TRPM4 | c.2925C>T p.F975= | Silent (SNP) | VAF 90/298 reads (30%) | catalogued as COSV53262122; called by muse, mutect2, varscan2
- TTC6 | c.2502A>T p.P834= | Silent (SNP) | VAF 45/137 reads (33%) | called by muse, mutect2, varscan2
- CHPF2 | c.*90G>A | 3'UTR (SNP) | VAF 59/195 reads (30%) | called by muse, mutect2, varscan2
- EMC4 | c.*39C>T | 3'UTR (SNP) | VAF 50/201 reads (25%) | called by muse, mutect2, varscan2
- HOXD4 | chr2:176150316 C>A | 5'Flank (SNP) | VAF 66/160 reads (41%) | called by muse, mutect2
- OBSCN | c.11660-2690G>A | Intron (SNP) | VAF 66/198 reads (33%) | catalogued as rs1286347684, COSV52821798; called by muse, mutect2, varscan2
- ZBED6 | c.*2695C>T | 3'UTR (SNP) | VAF 31/88 reads (35%) | called by muse, mutect2, varscan2
